Somatic mutation profile of tumor specimen TARGET-10-PARFTR-04A (aliquot TARGET-10-PARFTR-04A-01D) from TARGET case TARGET-10-PARFTR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,127 days).
Specimen TARGET-10-PARFTR-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8dc191f-a2bf-4060-915d-a074f61cc329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFTR-10A (Blood Derived Normal), aliquot TARGET-10-PARFTR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac74dc3d-e04b-4ccb-aa04-678d8c1cc3cd

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 3, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.820C>T p.R274* (on ENST00000332070 / NM_032458.3; = p.R275* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 227/230 reads (99%) | catalogued as rs1556019107, COSV59699330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP11C | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 87/88 reads (99%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV59559580; called by muse, mutect2, varscan2
- AXIN1 | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51983181; called by muse, mutect2, varscan2
- KDM1A | c.2282A>C p.Y761S | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56498388; called by muse, mutect2
- MDN1 | c.9530G>A p.G3177D | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs948346815, COSV101021831; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 179/338 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PANX3 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52511037; called by muse, mutect2, varscan2
- PDS5A | c.3685G>A p.G1229S | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV57822358; called by muse, mutect2, varscan2
- SETD2 | c.4792C>T p.R1598* | Nonsense Mutation (SNP) | VAF 142/309 reads (46%) | catalogued as COSV57429911; called by muse, mutect2, varscan2
- SLCO2B1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs375353895, COSV56932942; called by muse, mutect2, varscan2
- ANKS1B | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.177); called by muse, varscan2
- ANKS1B | c.1365T>A p.C455* | Nonsense Mutation (SNP) | VAF 73/182 reads (40%) | called by muse, varscan2
- ANKS1B | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, varscan2
- CENPU | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 18/575 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.617); called by muse, mutect2
- POLE | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPS6KA4 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- DNAI1 | c.2049G>A p.A683= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs555612830, COSV54278352; called by muse, mutect2, varscan2
- GLIS3 | c.1152C>T p.A384= | Silent (SNP) | VAF 63/129 reads (49%) | catalogued as rs756792178, COSV60923612; called by muse, mutect2, varscan2
- LRRC4 | c.861C>T p.T287= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV50813205; called by muse, mutect2, varscan2
- PTPRQ | c.6249T>A p.A2083= (on ENST00000616559; = p.A2050= on NM_001145026.2) | Silent (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- UBR4 | c.13780C>T p.L4594= | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as COSV64382769; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622573 C>T | 3'Flank (SNP) | VAF 21/358 reads (6%) | catalogued as rs946820177, COSV57541149; called by muse, mutect2
- STX4 | c.*2G>A | 3'UTR (SNP) | VAF 47/132 reads (36%) | catalogued as COSV58267801; called by muse, mutect2, varscan2
